Somatic mutation profile of tumor specimen TARGET-10-PARXMV-03A (aliquot TARGET-10-PARXMV-03A-01D) from TARGET case TARGET-10-PARXMV, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.4 years (4,523 days).
Specimen TARGET-10-PARXMV-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a02feddb-0d7d-47ec-8eab-0453744083e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARXMV-10A (Blood Derived Normal), aliquot TARGET-10-PARXMV-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2df85b08-a1eb-4af9-a845-dab9b7224213

The open-access MAF lists 32 somatic variants for this specimen: 18 protein-altering or splice-affecting, 9 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 9, In Frame Ins 2, 5'UTR 2, RNA 2, Intron 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC092143.1 | c.1804G>A p.V602I | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.983); catalogued as rs1057517908, COSV59247325; ClinVar: likely pathogenic; called by muse, mutect2
- CHD8 | c.4418G>A p.R1473H (on ENST00000646647 / NM_001170629.2; = p.R1194H on NM_020920.4) | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as rs779590262, COSV63218862; ClinVar: uncertain significance; called by muse, mutect2
- DEPDC5 | c.265G>C p.V89L | Missense Mutation (SNP) | VAF 79/161 reads (49%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.76); catalogued as COSV56693096; called by muse, varscan2
- DNM2 | c.215A>T p.Q72L | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV58958139, COSV99042617; called by muse, mutect2, varscan2
- ETV4 | c.1177G>A p.D393N | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1567705535, COSV52251645; called by muse, mutect2, varscan2
- FSIP2 | c.10025G>T p.G3342V | Missense Mutation (SNP) | VAF 51/113 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV58081002; called by muse, mutect2, varscan2
- IL7R | c.730_731insGGGGCTTCCATATCACGTGTCAAA p.L243_T244insRGFHITCQ | In Frame Ins (INS) | VAF 30/95 reads (32%) | catalogued as COSV57406755, COSV57406894; called by mutect2, pindel, varscan2
- LAMA4 | c.941T>A p.I314N (on ENST00000230538 / NM_001105206.3; = p.I307N on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as COSV57893290; called by muse, mutect2, varscan2
- MDM2 | c.973T>C p.C325R | Missense Mutation (SNP) | VAF 24/238 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50698220; called by muse, mutect2, varscan2
- NOS1 | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 43/85 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs80348085, COSV57606077; called by muse, mutect2, varscan2
- NOTCH1 | c.4754T>C p.L1585P | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53025649, COSV53029975, COSV53033143; called by muse, mutect2, varscan2
- PHF6 | c.346C>T p.R116* | Nonsense Mutation (SNP) | VAF 29/29 reads (100%) | catalogued as COSV59699190; called by muse, mutect2, varscan2
- RRBP1 | c.1286G>A p.G429D | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.793); catalogued as rs1166482543, COSV55697412; called by mutect2, varscan2
- SCAPER | c.1700T>C p.L567S | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.503); catalogued as COSV57736014; called by muse, mutect2, varscan2
- BCORL1 | c.3001dup p.Q1001Pfs*5 | Frame Shift Ins (INS) | VAF 6/56 reads (11%) | called by mutect2, pindel, varscan2
- HMCN1 | c.1706G>T p.R569M | Missense Mutation (SNP) | VAF 6/119 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.652); called by muse, mutect2
- LMLN2 | c.1318C>T p.P440S | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- NOTCH1 | c.7176_7177insGAGAAC p.M2392_Q2393insEN | In Frame Ins (INS) | VAF 29/53 reads (55%) | called by mutect2, pindel*, varscan2*
- ATP6V0D1 | c.318C>T p.I106= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs747420026, COSV52097095; called by muse, mutect2, varscan2
- FASTKD5 | c.1614G>A p.Q538= | Silent (SNP) | VAF 68/144 reads (47%) | catalogued as COSV53909434; called by muse, mutect2, varscan2
- FBXL8 | c.450C>T p.D150= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as rs369785877; called by muse, mutect2, varscan2
- GABRA1 | c.1320T>C p.A440= | Silent (SNP) | VAF 13/163 reads (8%) | called by muse, mutect2
- HERC2 | c.3108A>C p.S1036= | Silent (SNP) | VAF 66/151 reads (44%) | called by muse, mutect2, varscan2
- RAMP3 | c.381C>T p.V127= | Silent (SNP) | VAF 43/103 reads (42%) | catalogued as rs376139265; called by muse, mutect2, varscan2
- SLC45A1 | c.885G>A p.P295= | Silent (SNP) | VAF 20/32 reads (63%) | catalogued as rs547186750; called by muse, varscan2
- TRDV1 | chr14:22096618 CTCA>AATT | Silent (ONP) | VAF 38/185 reads (21%) | called by pindel, varscan2*
- USP1 | c.1206T>C p.T402= | Silent (SNP) | VAF 29/40 reads (73%) | called by muse, mutect2, varscan2
- ATOH8 | c.960+8794T>C | Intron (SNP) | VAF 16/28 reads (57%) | called by mutect2, varscan2
- BAGE2 | n.51G>T | RNA (SNP) | VAF 46/250 reads (18%) | called by muse, mutect2, varscan2
- HOXA3 | c.-59C>T | 5'UTR (SNP) | VAF 18/33 reads (55%) | catalogued as rs1276929666, COSV57829588; called by muse, mutect2, varscan2
- THAP10 | c.-117C>T | 5'UTR (SNP) | VAF 19/42 reads (45%) | catalogued as rs1019599029; called by muse, mutect2, varscan2
- ZNF720P1 | n.229A>C | RNA (SNP) | VAF 7/88 reads (8%) | called by muse, mutect2
